Gene-level copy-number profile of tumor specimen TCGA-DX-A7EI-01A from TCGA case TCGA-DX-A7EI, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 78.3 years (28,610 days).
Specimen TCGA-DX-A7EI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.bfae7468-70d5-4411-aa91-d05c8663a567.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A7EI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5184ff9a-8b0b-4364-9673-e82af5cb71fc

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 737; copy number 2: 15,572; copy number 3: 20,598; copy number 4: 17,970; copy number 5: 2,876; copy number 6: 723; copy number 7: 337; copy number 8: 146; copy number 9: 55; copy number 10: 254; copy number 11: 16; copy number 12: 132; copy number 13: 29; copy number 14: 26; copy number 15: 16; copy number 18: 66; copy number 20: 19; copy number 21: 1; copy number 22: 24; copy number 23: 77; copy number 24: 45; copy number 25: 20; copy number 26: 7; copy number 27: 20; copy number 29: 14; copy number 30: 14; copy number 35: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A7EI-01A-11D-A33D-01): tumor purity 0.89, ploidy 3.14, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,333 genes in 64 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,776,372–153,150,890, 25 genes, copy number 9–14: LCE1F, LCE1E, LCE1D, LCE1C, LCE1B, LCE1A, LCE6A, AL162596.1, SMCP, IVL, LINC01527, SPRR5, SPRR4, SPRR1A, SPRR3, AL356867.2, AL356867.1, SPRR1B, SPRR2D, SPRR2A, SPRR2B, SPRR2E, SPRR2F, SPRR2C, SPRR2G.
- chr1:153,203,430–153,396,771, 12 genes, copy number 9–13: LELP1, PRR9, AL161636.2, LORICRIN, PGLYRP3, PGLYRP4, RNU6-160P, S100A9, S100A12, LAPTM4BP1, S100A8, S100A15A.
- chr1:153,923,337–154,979,251, 59 genes, copy number 10: AL358472.5, DENND4B, CRTC2, SLC39A1, AL358472.7, MIR6737, AL358472.4, AL358472.3, CREB3L4, JTB, AL358472.6, AL358472.2, RAB13, RPS27, NUP210L, AL358472.1, RNU6-179P, RPS7P2, MIR5698, TPM3, RN7SL431P, MIR190B, C1orf189, C1orf43, UBAP2L, SNORA58B, HAX1, AL354980.1, RNU6-239P, RNU6-121P, AL354980.2, AQP10, ATP8B2, RNU7-57P, AL162591.1, RPSAP17, IL6R-AS1, IL6R, PSMD8P1, SHE, AL162591.2, TDRD10, UBE2Q1, UBE2Q1-AS1, AL592078.2, CHRNB2, AL592078.1, ADAR, AL606500.1, KCNN3, PMVK, AL451085.1, PBXIP1, Metazoa_SRP, PYGO2, AL451085.2, SHC1, CKS1B, MIR4258.
- chr1:155,562,042–155,885,199, 15 genes, copy number 13: ASH1L-AS1, AL353807.4, DAP3P1, AL353807.1, AL353807.2, MSTO1, AL353807.3, AL353807.5, YY1AP1, DAP3, AL162734.1, MSTO2P, GON4L, AL139128.1, SYT11.
- chr1:160,485,030–161,178,013, 37 genes, copy number 8: SLAMF6, AL138930.1, CD84, SLAMF1, SETP9, AL121985.1, CD48, SLAMF7, AL121985.3, AL121985.2, LY9, CD244, PPIAP37, ITLN1, AL354714.2, AL354714.3, AL354714.1, AL354714.4, ITLN2, F11R, AL591806.2, GLRX5P2, TSTD1, USF1, ARHGAP30, NECTIN4, NECTIN4-AS1, KLHDC9, PFDN2, NIT1, DEDD, AL591806.1, UFC1, AL590714.1, USP21, PPOX, B4GALT3.
- chr1:169,463,909–169,630,193, 5 genes, copy number 9: SLC19A2, AL021068.1, Z99572.1, F5, SELP.
- chr1:172,138,397–172,666,876, 11 genes, copy number 12: DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105, SUCO, RNU6-693P, FASLG.
- chr1:201,688,259–201,829,559, 4 genes, copy number 11 (within-gene range 3–11): IPO9-AS1, MIR5191, AL645504.1, RNU6-501P.
- chr1:217,426,992–221,336,489, 67 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:245,749,342–248,919,946, 136 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr4:37,241,910–38,701,517, 25 genes, copy number 8–10 (within-gene range 2–10): MIR4801, NWD2, C4orf19, AC022463.1, AC027607.1, RELL1, Y_RNA, AC108022.1, PGM2, AC021106.2, AC021106.1, TBC1D1, PTTG2, PSME2P4, MRPS33P2, AC098680.2, AC098680.1, LINC02513, AC024023.1, LINC01258, LINC01259, LINC02278, KLF3-AS1, AC021860.1, KLF3.
- chr5:58,198–4,147,429, 95 genes, copy number 10–12 (broad region; genes not listed).
- chr5:7,980,146–15,939,795, 122 genes, copy number 7–12 (broad region; genes not listed).
- chr6:4,427,963–4,611,919, 6 genes, copy number 8: RNA5SP202, AL162718.2, LINC02533, AL133393.1, AL034376.1, KU-MEL-3.
- chr6:43,844,878–44,450,425, 24 genes, copy number 7: LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2, SPATS1, CDC5L, MIR4642.
- chr6:44,727,921–45,664,349, 10 genes, copy number 8 (within-gene range 2–8): AL133334.1, SUPT3H, NUDT19P4, AL138880.2, RBM22P4, AL138880.1, MIR586, RUNX2, AL096865.1, RUNX2-AS1.
- chr8:5,363,371–11,564,599, 219 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr8:73,939,169–74,321,540, 12 genes, copy number 8 (within-gene range 4–8): ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1, JPH1.
- chr12:42,157,104–42,646,547, 16 genes, copy number 20–22 (within-gene range 5–22): YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1.
- chr12:42,929,848–43,163,110, 5 genes, copy number 29: AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461.
- chr12:47,788,426–47,943,048, 6 genes, copy number 20 (within-gene range 4–20): AC004466.3, AC004466.2, LINC02354, VDR, AC121338.1, AC121338.2.
- chr12:53,816,185–53,974,956, 9 genes, copy number 25 (within-gene range 4–25): RN7SKP289, HOXC13-AS, HOXC13, HOXC12, HOTAIR, AC012531.5, AC012531.7, AC012531.4, AC012531.6.
- chr12:57,512,688–58,244,865, 46 genes, copy number 24–26: MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103.
- chr12:58,920,639–59,812,576, 13 genes, copy number 14–27 (within-gene range 4–27): AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1.
- chr12:61,600,067–62,279,150, 5 genes, copy number 24 (within-gene range 4–24): DUX4L52, AC090629.1, TAFA2, RPL21P104, KRT8P19.
- chr12:64,452,090–64,990,646, 20 genes, copy number 22: TBK1, AC136977.1, RASSF3, AC078962.2, SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P.
- chr12:65,418,731–65,966,291, 11 genes, copy number 14 (within-gene range 4–14): KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1.
- chr12:66,950,754–68,474,902, 29 genes, copy number 10–27: AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1.
- chr12:68,746,125–68,971,570, 9 genes, copy number 29 (within-gene range 5–29): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5.
- chr12:69,212,108–71,586,310, 42 genes, copy number 9–30 (within-gene range 4–30): AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1.
- chr12:77,219,603–78,540,675, 10 genes, copy number 25: LINC02464, NAV3, AC073591.1, AC138331.1, AC073571.1, PRXL2AP1, LINC02424, AC128707.1, AC130415.1, AC079362.1.
- chr12:79,341,205–80,380,879, 17 genes, copy number 18 (within-gene range 4–21): AC027288.3, MIR1252, AC027288.2, AC027288.1, NOP56P3, PAWR, AC073569.2, PPP1R12A, AC073569.3, AC073569.1, RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P, OTOGL, AC078817.1.
- chr12:80,402,178–80,719,671, 5 genes, copy number 9–21: PTPRQ, AKIRIN1P1, AC074031.1, MYF6, MYF5.
- chr12:80,936,414–81,759,553, 6 genes, copy number 8–23 (within-gene range 2–23): ACSS3, AC078955.1, MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1.
- chr12:92,952,639–93,460,826, 15 genes, copy number 35: RNU6-1329P, LINC02413, AC138123.1, Y_RNA, AC021646.1, RPL41P5, AC138123.2, NACAP8, LINC02412, AC126172.1, AC124947.2, AC124947.1, NUDT4, UBE2N, Y_RNA.
- chr12:122,007,434–122,266,494, 11 genes, copy number 12: AC069503.1, BCL7A, AC156455.1, MLXIP, LRRC43, IL31, B3GNT4, AC048338.2, DIABLO, AC048338.1, VPS33A.
- chr19:34,254,552–34,428,273, 8 genes, copy number 11 (within-gene range 3–11): GARRE1, RPL29P33, AC010504.1, GPI, AC092073.1, PDCD2L, RN7SL154P, AC008747.1.
- chr19:34,779,412–36,045,972, 102 genes, copy number 18–23 (within-gene range 3–23) (broad region; genes not listed).
- chr20:57,710,156–58,309,451, 9 genes, copy number 8 (within-gene range 6–8): NKILA, AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L.
- chr21:20,256,752–21,543,329, 11 genes, copy number 9 (within-gene range 3–9): LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320, PPIAP1, NCAM2, AP001136.1.

Autosomal genes at a single copy (total copy number 1): 737. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
